Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JF-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, squamous
cell NOS 8070/3

Site Larynx NOS
C32.9

9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Larynx

I-) "Biopsy of the left vocal fold":

- Invasive moderately differentiated squamous cells carcinoma.

II-) "Right neck dissection specimen level IV":

- Absence of neoplasia (0/5).

III) "Right neck dissection specimen level III":

- Absence of neoplasia (0/18).

IV-) "Right neck dissection specimen level II":

- Absence of neoplasia (0/8).

V-) "Left neck dissection specimen level II":

- Absence of neoplasia (0/17).

VI-) "Left neck dissection specimen level III":

- Metastatic squamous cell carcinoma in one lymph node (1/7), without capsular involvement.

VII) "Left neck dissection specimen level IV":

- Absence of neoplasia (0/11).

VIII) Product of thyroid and larynx resection.

- Moderately differentiated squamous cell carcinoma, measuring 5.0 x 3.0 cm on the greatest dimensions, affecting the following structures:

- * Glottic, supraglottic and infraglottic regions on the left.

- * Infraglottic on the right.

- * Piriform sinus on the left.

- * Cricoid, arytenoid and thyroid cartilages.

- * Thyroid isthmus.

- * Soft tissues adjacent to the larynx.

- * Trachea.

- Angiolymphatic and perineural invasion not observed.

- Left soft tissue margins involved by neoplasia.

- Other surgical margins uninvolved by neoplasia.

[page 2 of 2]
- Right thyroid lobe with no particularities.
- Small follicular adenoma on the left thyroid lobe.

SUMMARY OF HISTOLOGICAL FINDINGS:

- Grade 2 squamous cell carcinoma of the larynx, transglottic on the left and infraglottic on the right with involvement of the adjacent soft tissues, thyroid and hypopharynx on the left.
- Right lymph nodes: 0/31
- Left lymph nodes: 1/35 without capsular involvement.

ICDPA Discrepancy		☒

Source: NCI Genomic Data Commons file c03faf25-9bd8-43bb-a380-e9e6d308608d (TCGA-UF-A7JF.F2F30103-A0E4-4377-9132-2DB7C2609064.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).